Somatic mutation profile of tumor specimen 0DSS5S from CCDI case PBCICT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 5.9 years (2,159 days).
Specimen 0DSS5S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ca94d8e-0b6c-4737-89dc-eb1b1c1490c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSS6A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45b485f1-8cad-4d4c-aff0-702e2ae9ecf7

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 30/267 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- STAG2 | c.1535-1G>T p.X512_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as rs1280851964; called by mutect2, varscan2
